Somatic mutation profile of tumor specimen MP2PRT-PAUYXJ-TMP1-A (aliquot MP2PRT-PAUYXJ-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUYXJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (952 days).
Specimen MP2PRT-PAUYXJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6dabc11-9cfb-4f2d-8a11-86f04ca8edcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUYXJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUYXJ-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14826322-52c3-46a4-be9c-f25856a7b674

The open-access MAF lists 37 somatic variants for this specimen: 28 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 7, Nonsense Mutation 3, Intron 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AVPR1A | c.1081C>G p.Q361E | Missense Mutation (SNP) | VAF 17/438 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV54547297; called by muse, mutect2
- DOK6 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs753953695, COSV101234252; called by muse, mutect2
- F5 | c.2518C>G p.L840V | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV63121837; called by muse, mutect2, varscan2
- KCNH7 | c.3463C>G p.H1155D | Missense Mutation (SNP) | VAF 114/331 reads (34%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as COSV100147737; called by muse, mutect2, varscan2
- KIRREL2 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 18/628 reads (3%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.478); catalogued as rs1338488077, COSV99383816; called by muse, mutect2
- OBI1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56147107; called by muse, mutect2, varscan2
- POSTN | c.2425C>T p.Q809* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as rs1168501482; called by muse, varscan2
- PRDM9 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs767394233, COSV57005322, COSV57010207; called by muse, mutect2, varscan2
- RBSN | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 50/446 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs752920323; called by muse, mutect2, varscan2
- RMC1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT tolerated (0.68); PolyPhen benign (0.118); catalogued as rs1251850468, COSV52572854; called by muse, mutect2
- TET2 | c.2057G>C p.R686T | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV54430389; called by muse, mutect2, varscan2
- ZNF320 | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV67087713; called by muse, mutect2, varscan2
- ARL13B | c.497C>T p.S166L (on ENST00000394222 / NM_001174150.2; = p.S59L on NM_144996.4) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- DNAJB14 | c.635C>G p.S212* | Nonsense Mutation (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- ERLEC1 | c.427-1G>C p.X143_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- FCSK | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 27/375 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.024); called by muse, mutect2
- KRTAP27-1 | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2
- LTN1 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- LYSMD3 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MAGI1 | c.2236C>G p.Q746E | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- NXPE3 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.454); called by muse, mutect2
- PRDM13 | c.1361A>C p.H454P | Missense Mutation (SNP) | VAF 191/572 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC39A10 | c.1756G>C p.E586Q | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLC7A13 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 105/337 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBL1XR1 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 21/168 reads (13%) | called by muse, mutect2, varscan2
- TTC21B | c.3010G>A p.D1004N | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- UHRF1 | c.2332C>G p.L778V (on ENST00000612630 / NM_001290050.1; = p.L791V on NM_013282.4) | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WTIP | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CASZ1 | c.5247C>T p.P1749= | Silent (SNP) | VAF 62/163 reads (38%) | called by mutect2, varscan2
- GRM1 | c.2226C>G p.V742= | Silent (SNP) | VAF 123/381 reads (32%) | called by muse, mutect2, varscan2
- LGI2 | c.738C>T p.I246= | Silent (SNP) | VAF 154/429 reads (36%) | catalogued as rs757666849, COSV66122856, COSV66123798; called by muse, mutect2, varscan2
- LMNB1 | c.354C>A p.L118= | Silent (SNP) | VAF 97/304 reads (32%) | called by muse, mutect2, varscan2
- MYO7B | c.642G>A p.G214= | Silent (SNP) | VAF 21/422 reads (5%) | catalogued as COSV67349195; called by muse, mutect2
- PDHA2 | c.408G>A p.L136= | Silent (SNP) | VAF 34/410 reads (8%) | catalogued as rs755229100; called by muse, mutect2
- ROS1 | c.3378C>T p.F1126= | Silent (SNP) | VAF 28/193 reads (15%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+931G>A | Intron (SNP) | VAF 18/537 reads (3%) | catalogued as rs1272704606; called by muse, mutect2
- PLCE1 | c.1207-42814G>A | Intron (SNP) | VAF 55/183 reads (30%) | called by muse, mutect2, varscan2
